CPTAC case C3L-09191 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/fecd8f3c-cbd8-4338-a37e-feca7c6c6fa9

Demographics
Sex at birth: female; Race: white; Year of birth: 1990; Vital status: Alive; Country of birth: Romania.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Gastric antrum; Age at diagnosis: 32.1 years (11,708 days); Year of diagnosis: 2022; AJCC staging edition: 8th; AJCC pathologic T: T3; AJCC pathologic N: N3b; AJCC pathologic stage: Stage IIIB; Tumor grade: G3; Residual disease: R0; Days to last known disease status: 718 days (2.0 years); Progression or recurrence: no; Days to last follow up: 718 days (2.0 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5 cm; Lymph node involvement: Positive; Lymph nodes positive: 18; Lymph nodes tested: 19.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 25 days; Days to treatment end: 48 days; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Days to treatment start: 25 days; Days to treatment end: 48 days; Treatment outcome: Stable Disease.

Follow-up (1 entry)
- Days to follow up: 349 days; Disease response: Complete Response; Karnofsky performance status: 80; ECOG performance status: 1.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 14; Cigarettes per day: 20; Tobacco smoking onset year: 2008; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-09191-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 20 days; Initial weight: 126 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-09191-21: Section location: Antrum; Percent tumor nuclei: 75; Percent necrosis: 0.
- Sample C3L-09191-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 20 days; Initial weight: 220 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-09191-22: Section location: Antrum; Percent tumor nuclei: 60; Percent necrosis: 0.
- Sample C3L-09191-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 20 days; Method of sample procurement: Blood Draw.
